TCGA case TCGA-FC-A4JI — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/30f623a3-dae7-41da-ab10-8786d094209e

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Vietnam; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 71.0 years (25,931 days); Year of diagnosis: 2012; Method of diagnosis: Core Biopsy; AJCC clinical T: T4; AJCC clinical M: M0; AJCC pathologic T: T3a; Primary gleason grade: Pattern 5; Secondary gleason grade: Pattern 3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Gleason score: 8.
   Pathology details: Consistent pathology review: Yes; Tumor level prostate: Apex / Middle / Base; Zone of origin prostate: Central zone.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 51 days; Days to treatment end: 147 days; Treatment dose: 70 Gy; Treatment outcome: Complete Response; Number of fractions: 7; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Bicalutamide; Days to treatment start: 52 days; Days to treatment end: 143 days; Treatment outcome: Complete Response.

Follow-up (5 entries)
- Day 12 (initial diagnosis): Days to imaging: 12 days; Imaging type: Bone Scan, NOS; Imaging result: Negative.
- Day 16 (initial diagnosis): Days to imaging: 16 days; Imaging type: CT Scan; Imaging anatomic site: Abdomen / Pelvis; Imaging findings: Extraprostatic Extension, Localized.
- Days to follow up: 29 days; Disease response: Tumor Free.
- Days to follow up: 409 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 877 days (2.4 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FC-A4JI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 630 mg.
  Slide TCGA-FC-A4JI-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 7; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FC-A4JI-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FC-A4JI-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Method initial path diagnosis: Core needle biopsy; Bone scan results: Normal (no evidence of prostate cancer) [cM0]; Ct scan ab pelvis indicator: Yes; Diagnostic mri performed: No; Lymph nodes examined: No; New tumor event diagnosis indicator: No.
- Tumor levels: Tumor level: Apex; Tumor level: Middle; Tumor level: Base.
- Diagnostic ct abd pelvis results: Ct scan ab pelvis results: Extraprostatic Extension  Localized (e.g. seminal vesicles).
- Stage record, Gleason grading: Gleason pattern primary: 5; Gleason pattern secondary: 3.
- Drug treatment: Pharmaceutical therapy drug name: Casodex.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 877 days; disease-specific survival: no event (censored), 877 days; disease-free interval: no event (censored), 877 days; progression-free interval: no event (censored), 877 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FC-A4JI-01A-11D-A256-01): tumor purity 0.65, ploidy 3.4, whole-genome doublings 1.
